Somatic mutation profile of tumor specimen TCGA-EL-A4JW-01A (aliquot TCGA-EL-A4JW-01A-11D-A257-08) from TCGA case TCGA-EL-A4JW, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 38.1 years (13,928 days).
Specimen TCGA-EL-A4JW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd42c9cc-35c1-43b4-a559-e266ada2b693.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A4JW-11A (Solid Tissue Normal), aliquot TCGA-EL-A4JW-11A-12D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd326c5b-bd74-4626-96c8-5a9459cd1e74

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CELF5 | c.726C>G p.S242R | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV53011230; called by muse, mutect2, varscan2
- FAM120B | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV53002980; called by muse, mutect2
- GOT2 | c.860G>T p.R287L | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55331390; called by muse, mutect2, varscan2
- RPL18A | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.04); catalogued as COSV55829993; called by muse, mutect2, varscan2
- SLC6A8 | c.683C>A p.P228Q | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as COSV99466451; called by muse, mutect2, varscan2
- UQCRC1 | c.949A>G p.T317A | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.992); catalogued as rs754870725, COSV52551410; called by muse, mutect2, varscan2
- GPR149 | c.1616del p.P539Lfs*37 | Frame Shift Del (DEL) | VAF 15/37 reads (41%) | called by mutect2, pindel, varscan2
- ZNF786 | c.2285A>G p.N762S | Missense Mutation (SNP) | VAF 8/226 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PRRC2C | c.2622A>G p.Q874= (on ENST00000367742; = p.Q872= on NM_015172.4) | Silent (SNP) | VAF 38/111 reads (34%) | catalogued as COSV58903920; called by muse, mutect2, varscan2
